Gene-level copy-number profile of tumor specimen TCGA-D9-A149-06A from TCGA case TCGA-D9-A149, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D9-A149-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.e4a72423-ccd6-42c2-a4fa-2e2f55b13b9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A149-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9cf7e92-5774-4347-b434-4e4754019665

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,369; copy number 2: 7,016; copy number 3: 14,655; copy number 4: 28,627; copy number 5: 1,991; copy number 6: 1,885; copy number 7: 135; copy number 9: 1,178; copy number 10: 1,059; copy number 11: 1,841; copy number 12: 55; copy number 15: 3; copy number 16: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A149-06A-11D-A194-01): tumor purity 0.57, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,142 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–54,266,280, 1,474 genes, copy number 9–10 (within-gene range 6–10) (broad region; genes not listed).
- chr6:54,190,206–58,438,364, 50 genes, copy number 10: AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr6:62,611,153–75,718,281, 152 genes, copy number 10–15 (broad region; genes not listed).
- chr13:23,169,835–36,920,765, 251 genes, copy number 10–16 (broad region; genes not listed).
- chr15:19,878,555–101,933,350, 2,215 genes, copy number 10–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
